Somatic mutation profile of tumor specimen SM-JU33F (aliquot 7316UP-574) from CPTAC case C298152, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU33F: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b145255-0819-4b87-bdbb-010498ce3ee1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105208 (Blood Derived Normal), aliquot 7316UP-426-1105208; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9eacd5c4-fcf5-4886-90e6-ce8562f7a241

The open-access MAF lists 38 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 10, Nonsense Mutation 1, Intron 1, 5'UTR 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs864622341, COSV64290156; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- USH2A | c.10450C>T p.R3484* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as rs111033379, CM080610, COSV56427899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs779902900, COSV60922721; called by muse, mutect2, varscan2
- CPAMD8 | c.1474G>A p.G492S (on ENST00000651564; = p.G445S on NM_015692.5) | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs574048580; called by muse, mutect2, varscan2
- CPZ | c.1862C>T p.A621V (on ENST00000360986 / NM_001014447.3; = p.A610V on NM_003652.3) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs201930593, COSV100249106; called by muse, mutect2, varscan2
- JPH1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs748452859, COSV60608792; called by muse, mutect2, varscan2
- MTHFR | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775829502, COSV100928224; called by muse, mutect2
- MUC5B | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs554624154; called by muse, mutect2, varscan2
- NPNT | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs778565408, COSV59753816; called by muse, mutect2, varscan2
- OBSCN | c.13361C>T p.T4454M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs758896862, COSV52750133, COSV52751888; called by muse, mutect2, varscan2
- PCLO | c.8125C>A p.H2709N | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV61653611; called by muse, mutect2, varscan2
- PLCG1 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54814695; called by muse, mutect2, varscan2
- RELB | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); catalogued as rs571786771, COSV55513078; called by muse, mutect2, varscan2
- RGS9 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 133/452 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs913010766, COSV52225932; called by muse, mutect2, varscan2
- SIPA1L3 | c.1345G>A p.V449M | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs370319919; called by muse, mutect2, varscan2
- TRPV6 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs775866936; called by muse, mutect2, varscan2
- WDR88 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.32); catalogued as rs201611292; called by muse, mutect2, varscan2
- AKAP9 | c.5905C>A p.Q1969K (on ENST00000359028; = p.Q1937K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- BTN3A3 | c.744G>T p.W248C | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EML3 | c.1074C>A p.F358L | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IRS1 | c.173G>T p.S58I | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- OR52B4 | c.769G>C p.G257R | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PABPN1 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGB5 | c.397T>A p.F133I | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADIPOQ | c.624C>T p.G208= | Silent (SNP) | VAF 110/219 reads (50%) | catalogued as rs200876636; called by muse, mutect2, varscan2
- APBB1 | c.30G>A p.S10= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs777578946; called by muse, mutect2, varscan2
- CNTNAP2 | c.2037C>T p.A679= | Silent (SNP) | VAF 90/389 reads (23%) | catalogued as rs539741829, COSV62276109; called by muse, mutect2, varscan2
- CPNE4 | c.93G>A p.A31= | Silent (SNP) | VAF 55/210 reads (26%) | catalogued as rs368853915, COSV70193650; called by muse, mutect2, varscan2
- FAM83H | c.1992G>A p.K664= | Silent (SNP) | VAF 88/360 reads (24%) | called by muse, mutect2, varscan2
- FTCD | c.1479C>T p.G493= | Silent (SNP) | VAF 132/558 reads (24%) | catalogued as rs576503541, COSV52430942; called by muse, mutect2, varscan2
- GABRD | c.153C>T p.Y51= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as rs148496176; called by muse, mutect2, varscan2
- RAB6C | c.606C>T p.S202= | Silent (SNP) | VAF 34/207 reads (16%) | catalogued as COSV101308492; called by muse, mutect2, varscan2
- SF3B3 | c.1848C>A p.I616= | Silent (SNP) | VAF 48/181 reads (27%) | called by muse, mutect2, varscan2
- TSBP1 | c.495C>T p.H165= (on ENST00000617061; = p.P175S on NM_006781.5) | Silent (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2
- AC058822.1 | c.1018-288066G>C | Intron (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- GNL1 | c.-940C>T | 5'UTR (SNP) | VAF 103/385 reads (27%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159896 G>A | 5'Flank (SNP) | VAF 21/73 reads (29%) | catalogued as rs1413811503; called by muse, mutect2, varscan2
- SNORD116-6 | n.84G>A | RNA (SNP) | VAF 31/137 reads (23%) | catalogued as rs756590960; called by muse, mutect2, varscan2
